Gene-level copy-number profile of tumor specimen TCGA-4Z-AA84-01A from TCGA case TCGA-4Z-AA84, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.3 years (22,397 days).
Specimen TCGA-4Z-AA84-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.5040809f-4a4a-4b4c-87db-e936df9a68cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA84-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be818cff-1649-4d6d-86c7-7f8d85dd691b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 540; copy number 2: 2,551; copy number 3: 16,375; copy number 4: 13,612; copy number 5: 9,862; copy number 6: 6,682; copy number 7: 4,387; copy number 8: 3,316; copy number 9: 820; copy number 10: 510; copy number 11: 577; copy number 12: 188; copy number 13: 65; copy number 14: 47; copy number 15: 203; copy number 16: 24; copy number 17: 12; copy number 18: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA84-01A-11D-A390-01): tumor purity 0.43, ploidy 4.72, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,021,545, 3 genes (within-gene range 0–3): AC093865.1, LINC01878, PCED1CP.
- chr11:46,396,414–46,700,619, 7 genes (within-gene range 0–5): AMBRA1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 10,171 genes in 66 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:54,285,405–63,326,984, 136 genes, copy number 7 (broad region; genes not listed).
- chr1:145,719,471–154,548,147, 420 genes, copy number 8 (broad region; genes not listed).
- chr1:158,774,222–166,876,264, 242 genes, copy number 8–13 (broad region; genes not listed).
- chr1:182,327,068–185,657,168, 81 genes, copy number 8 (broad region; genes not listed).
- chr1:190,878,145–197,478,455, 61 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:210,231,456–211,853,703, 38 genes, copy number 7: SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1.
- chr1:216,503,246–246,507,312, 606 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr1:246,945,547–248,919,946, 111 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:49,202,126–52,702,615, 27 genes, copy number 8: AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431.
- chr2:77,652,025–92,035,000, 305 genes, copy number 7 (broad region; genes not listed).
- chr2:101,252,886–103,623,830, 40 genes, copy number 8: CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1.
- chr2:167,293,171–189,784,364, 346 genes, copy number 7–11 (broad region; genes not listed).
- chr3:11,745–4,467,273, 39 genes, copy number 7 (within-gene range 6–7): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR.
- chr3:7,519,741–14,394,757, 147 genes, copy number 7–8 (broad region; genes not listed).
- chr4:93,318,623–98,143,476, 28 genes, copy number 7 (within-gene range 6–7): AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28, AC096585.1, COX7A2P2, AC108515.1, STPG2, AC034154.1, STPG2-AS1.
- chr5:102,500,541–105,392,970, 25 genes, copy number 7: AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1.
- chr5:166,905,222–170,141,940, 40 genes, copy number 7: LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1, SLIT3, SLIT3-AS2, MIR218-2, Y_RNA, AC011389.1, AC011389.2, SLIT3-AS1, MIR585, RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41.
- chr6:3,904,920–5,918,844, 47 genes, copy number 10: AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1, AL162718.1, AL159166.1, AL162718.3, RNA5SP202, AL162718.2, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1, AL035653.1, PPP1R3G, LYRM4, MIR3691, FARS2, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P.
- chr6:7,881,522–10,709,782, 37 genes, copy number 9–11 (within-gene range 4–11): BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1.
- chr6:13,214,056–17,131,378, 60 genes, copy number 9: RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1.
- chr6:163,671,577–170,738,536, 143 genes, copy number 9 (broad region; genes not listed).
- chr7:62,275,361–159,233,377, 1,936 genes, copy number 7–10 (broad region; genes not listed).
- chr8:46,028,804–54,479,963, 131 genes, copy number 10 (broad region; genes not listed).
- chr8:67,422,038–145,066,685, 1,208 genes, copy number 7–18 (within-gene range 6–18) (broad region; genes not listed).
- chr9:35,490,111–35,828,732, 32 genes, copy number 7 (within-gene range 3–7): RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3.
- chr9:80,357,029–83,069,143, 32 genes, copy number 7: NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1.
- chr10:36,432,882–38,783,108, 57 genes, copy number 8: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:49,817,778–54,725,816, 42 genes, copy number 8: AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr13:25,301,556–45,436,660, 347 genes, copy number 8–12 (within-gene range 5–12) (broad region; genes not listed).
- chr15:43,106,225–46,100,392, 120 genes, copy number 7 (broad region; genes not listed).
- chr15:59,105,126–60,479,160, 36 genes, copy number 7: CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2, FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.2, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2.
- chr15:91,853,708–93,569,483, 38 genes, copy number 8 (within-gene range 4–8): SLCO3A1, AC116903.2, AC116903.1, DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2.
- chr16:16,290,135–19,858,467, 98 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr16:23,278,231–28,323,849, 98 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr17:39,665,349–41,335,733, 113 genes, copy number 8–11 (broad region; genes not listed).
- chr17:56,791,913–61,863,528, 173 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:76,038,775–82,212,830, 268 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).
- chr19:94,062–39,846,379, 1,749 genes, copy number 7–15 (broad region; genes not listed).
- chr19:47,255,850–48,599,425, 61 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
